CPTAC case C3L-02102 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/53e3396f-6b38-457b-83f9-bf9ab2c47ffc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 65.1 years (23,767 days); Year of diagnosis: 2014; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage 0; Residual disease: R1; Last known disease status: Tumor free; Days to last known disease status: 2,510 days (6.9 years); Days to last follow up: 2,510 days (6.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7.1 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 2; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 1,653 days (4.5 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 2,019 days (5.5 years); Disease response: Tumor Free; ECOG performance status: 1.
- Days to follow up: 2,355 days (6.4 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 2,510 days (6.9 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 27.8; Cigarettes per day: 15; Tobacco smoking onset year: 1980; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 42.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02102-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1,373 days (3.8 years); Initial weight: 227 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02102-22: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-02102-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1,373 days (3.8 years); Method of sample procurement: Blood Draw.
